Somatic mutation profile of tumor specimen TCGA-A6-5659-01B (aliquot TCGA-A6-5659-01B-04D-A270-10) from TCGA case TCGA-A6-5659, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 82.2 years (30,028 days).
Specimen TCGA-A6-5659-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97853721-9ec1-464f-9259-3bb7af3e6e55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-5659-10A (Blood Derived Normal), aliquot TCGA-A6-5659-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d5596b1-89e1-4573-9da2-da6717bdfd51

The open-access MAF lists 191 somatic variants for this specimen: 143 protein-altering or splice-affecting, 43 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 43, Nonsense Mutation 14, Frame Shift Del 4, Intron 4, Splice Region 1, Frame Shift Ins 1, In Frame Del 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2097G>A p.W699* | Nonsense Mutation (SNP) | VAF 24/35 reads (69%) | catalogued as rs1060503282, CM950072, COSV57342069; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 64/119 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 55/167 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28937318, CM020301, CM100648, COSV61123792; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 9/13 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1276A>G p.T426A | Missense Mutation (SNP) | VAF 77/88 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs772861392, COSV52706497; called by muse, mutect2, varscan2
- ABCA2 | c.3227C>T p.S1076L (on ENST00000614293; = p.S1046L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs369448216; called by muse, mutect2, varscan2
- ADCY8 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV53895915, COSV53906214; called by muse, mutect2, varscan2
- ALDH8A1 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781744419, COSV55641768; called by muse, mutect2, varscan2
- ARPP21 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs535145550, COSV51792286, COSV51800995; called by muse, varscan2
- ASIC5 | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV73332711; called by muse, mutect2, varscan2
- ASMT | c.721C>A p.P241T (on ENST00000381229; = p.P269T on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.529); catalogued as rs775384287, COSV67109842; called by muse, mutect2, varscan2
- ATG9B | c.2149C>T p.L717F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV52489583; called by muse, mutect2, varscan2
- BAIAP2 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1048795319, COSV58335272; called by muse, mutect2, varscan2
- BRPF3 | c.2561del p.P854Rfs*6 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as rs1413008697, COSV60208966; called by pindel, varscan2
- CACNA2D3 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 3/9 reads (33%) | catalogued as rs1417940298, COSV55537866; called by muse, mutect2
- CANT1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV56605509; called by muse, mutect2, varscan2
- CAV3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs116840777, CM010790, COSV57478483; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC14 | c.1855C>T p.R619C (on ENST00000488653; = p.R571C on NM_022757.5) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs374105030, COSV59944734; called by muse, mutect2, varscan2
- CCT8L2 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100743053, COSV63462385; called by muse, mutect2, varscan2
- CD109 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV54649255; called by muse, mutect2, varscan2
- CDH10 | c.1456G>T p.A486S | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as COSV100051511; called by muse, mutect2
- CDH4 | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779693148, COSV64663178; called by muse, mutect2
- CDK12 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101420452; called by muse, mutect2, varscan2
- CHRNA3 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as rs777301381, COSV58776252; called by muse, varscan2
- CHST2 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58885500; called by muse, mutect2, varscan2
- CHUK | c.1438T>G p.L480V | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64917854; called by muse, mutect2, varscan2
- CLK2 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as rs779725189, COSV100751879; called by muse, mutect2
- CLSTN2 | c.2122C>A p.P708T | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); catalogued as COSV101515721; called by muse, mutect2, varscan2
- CNOT11 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV56819782; called by muse, varscan2
- CNTN4 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs761965189, COSV61872783; called by muse, mutect2, varscan2
- COL6A6 | c.4808G>C p.G1603A | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62024755; called by muse, mutect2, varscan2
- CPQ | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.243); catalogued as COSV99613654; called by muse, varscan2
- CREB3L4 | c.636G>A p.K212= | Splice Region (SNP) | VAF 7/29 reads (24%) | catalogued as COSV55132094; called by muse, mutect2, varscan2
- CSMD3 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV52176756; called by muse, mutect2, varscan2
- CUBN | c.6793G>T p.D2265Y | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64715397; called by muse, mutect2, varscan2
- CWF19L2 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 60/83 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV56512380; called by muse, mutect2, varscan2
- DAW1 | c.551C>A p.S184* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | catalogued as COSV59368095; called by muse, mutect2, varscan2
- DHX8 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52253304; called by muse, mutect2, varscan2
- DISC1 | c.1808C>T p.T603M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as rs148111679, CM080195, COSV54407026; called by muse, mutect2, varscan2
- DKK2 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1172140233, COSV53397427; called by mutect2, varscan2
- DLGAP2 | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs545242845, COSV70098004; called by muse, mutect2, varscan2
- EP300 | c.1282+1G>A p.X428_splice | Splice Site (SNP) | VAF 16/34 reads (47%) | catalogued as COSV54331805; called by muse, mutect2, varscan2
- EPG5 | c.4909C>T p.L1637F | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV56349521; called by muse, mutect2, varscan2
- FAM120AOS | c.436T>A p.C146S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV52904762; called by muse, mutect2, varscan2
- FAM133A | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 133/140 reads (95%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.295); catalogued as COSV59075224; called by muse, mutect2, varscan2
- FAM47B | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 122/130 reads (94%) | SIFT tolerated (0.05); PolyPhen benign (0.25); catalogued as COSV61453842, COSV61456163; called by muse, mutect2, varscan2
- FANCA | c.1095G>T p.M365I | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV66881578; called by muse, mutect2, varscan2
- FFAR1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50052516; called by muse, mutect2, varscan2
- FHOD1 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs781200583, COSV50760743; called by muse, mutect2
- FRA10AC1 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.78); catalogued as COSV63271963; called by muse, mutect2, varscan2
- FREM1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs780511700, COSV66530629; called by muse, mutect2, varscan2
- GDAP1L1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs779006217, COSV61157121; called by muse, mutect2, varscan2
- GIMAP5 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0.146); catalogued as rs752298821, COSV57529982; called by muse, mutect2, varscan2
- GOT1 | c.1172G>A p.S391N | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV63201601; called by muse, mutect2, varscan2
- HEXIM2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs773017611, COSV56236383; called by muse, mutect2, varscan2
- IKZF1 | c.676T>A p.Y226N | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV100498396; called by muse, varscan2
- INPP5B | c.1106A>G p.N369S (on ENST00000373023; = p.N289S on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs757163667, COSV65960823; called by muse, mutect2, varscan2
- IQCA1 | c.1936G>T p.V646F | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54501755; called by muse, mutect2, varscan2
- IQSEC1 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.459); catalogued as rs754235473, COSV56223830; called by muse, mutect2, varscan2
- ITPRID1 | c.1868G>A p.S623N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV60074440; called by muse, mutect2, varscan2
- IVL | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.068); catalogued as COSV64216203; called by muse, mutect2, varscan2
- KCNA1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as COSV66836436; called by muse, mutect2, varscan2
- KCNS2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54638511; called by muse, mutect2, varscan2
- KDM4A | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV64959528; called by muse, mutect2, varscan2
- KIAA0319L | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs142007809; called by mutect2, varscan2
- KRT39 | c.773C>A p.S258Y | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100842173, COSV62917211; called by muse, mutect2, varscan2
- KRTAP19-5 | c.45C>A p.Y15* | Nonsense Mutation (SNP) | VAF 16/24 reads (67%) | catalogued as COSV100478566; called by muse, varscan2
- LCE2B | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as COSV100909310; called by muse, mutect2, varscan2
- MAGEC2 | c.517A>C p.K173Q | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as COSV55999274; called by muse, mutect2, varscan2
- MAST2 | c.2681G>A p.R894Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.349); catalogued as rs753126429, COSV63618108; called by muse, mutect2, varscan2
- MME | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64707342; called by muse, mutect2, varscan2
- MMP16 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs757895279, COSV54164309; called by muse, mutect2, varscan2
- MUC5B | c.6908C>T p.S2303L | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs772020683, COSV71592011; called by muse, mutect2, varscan2
- MYC | c.437C>T p.S146L (on ENST00000377970; = p.S161L on NM_002467.6) | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52367052; called by muse, mutect2, varscan2
- MYO1E | c.1487A>G p.N496S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV55686943; called by mutect2, varscan2
- MYT1L | c.1880C>T p.T627M | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV101221047, COSV67712558; called by muse, mutect2, varscan2
- NAALADL2 | c.1606A>C p.S536R | Missense Mutation (SNP) | VAF 84/188 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV69156110; called by muse, varscan2
- NIPBL | c.6182C>T p.P2061L | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs587783999, COSV56950900; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN2 | c.840G>T p.Q280H | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.465); catalogued as COSV55453005; called by muse, mutect2, varscan2
- OGDH | c.2912C>T p.P971L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV56049633; called by muse, mutect2, varscan2
- OR10H2 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100008777; called by muse, mutect2, varscan2
- OR10J5 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58385563, COSV58386029; called by muse, mutect2, varscan2
- OTOF | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as rs769432101, COSV55517018; called by mutect2, varscan2
- OTOGL | c.4846C>T p.R1616W (on ENST00000547103; = p.R1607W on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536538111, COSV54016630; called by muse, mutect2, varscan2
- PARP9 | c.368G>A p.W123* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV64450662; called by muse, mutect2, varscan2
- PCDH17 | c.998C>A p.A333D | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100931657; called by muse, mutect2, varscan2
- PCDHA6 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.044); catalogued as COSV65341983; called by muse, mutect2, varscan2
- PCDHGA4 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.011); catalogued as rs753002448, COSV53945296; called by muse, mutect2, varscan2
- PDGFRA | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57267905; called by muse, mutect2, varscan2
- PON3 | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55699252; called by muse, mutect2, varscan2
- POTEF | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.948); catalogued as rs754169172, COSV62541227; called by muse, mutect2, varscan2
- PPFIA2 | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61020166; called by muse, mutect2, varscan2
- PPP1R9A | c.1785A>T p.Q595H | Missense Mutation (SNP) | VAF 109/167 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV56892178; called by muse, mutect2, varscan2
- PPP2R2B | c.119C>T p.A40V (on ENST00000394409; = p.A106V on NM_181674.2) | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1554126530, COSV60764226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR19 | c.653G>T p.S218I | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV56625255; called by muse, mutect2, varscan2
- PTPRU | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs775440824, COSV60527630; called by muse, mutect2, varscan2
- RGS20 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.323); catalogued as rs550487524, COSV52016836; called by mutect2, varscan2
- RXRB | c.484A>T p.I162F | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.551); catalogued as COSV63399705; called by muse, mutect2, varscan2
- SAMD7 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 41/86 reads (48%) | catalogued as COSV59418650; called by muse, mutect2, varscan2
- SCN1A | c.3536C>T p.A1179V (on ENST00000303395 / NM_001202435.3; = p.A1168V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.18); catalogued as rs780475706; called by muse, mutect2, varscan2
- SCN9A | c.4351T>G p.L1451V (on ENST00000303354; = p.L1440V on NM_002977.3) | Missense Mutation (SNP) | VAF 114/278 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57609404; called by muse, mutect2, varscan2
- SCRN1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs766147656, COSV54130661; called by muse, mutect2, varscan2
- SLC22A2 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs768194904, COSV65266300; called by muse, mutect2, varscan2
- SMARCE1 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as rs1251821702, COSV52860590; called by muse, mutect2, varscan2
- SNPH | c.396G>T p.Q132H | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67870605; called by muse, mutect2, varscan2
- SORCS1 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV53848358, COSV53865482; called by muse, mutect2, varscan2
- SPATA18 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs779355129, COSV54644470; called by muse, mutect2, varscan2
- STON1 | c.1713C>A p.H571Q | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as rs1262877194, COSV59130422; called by muse, mutect2, varscan2
- TBC1D22B | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.913); catalogued as rs767058134, COSV65142535; called by muse, mutect2, varscan2
- TCHHL1 | c.846G>T p.K282N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as COSV64285688; called by muse, mutect2, varscan2
- TDRD7 | c.3121C>T p.R1041* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV62429379, COSV62430190; called by muse, mutect2, varscan2
- TMEM132B | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750179973, COSV54766965; called by muse, mutect2, varscan2
- TNFRSF11A | c.545T>C p.V182A | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV54023414; called by muse, mutect2, varscan2
- TRIM3 | c.1376C>A p.T459K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV100624408; called by muse, mutect2, varscan2
- TSPEAR | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs113059777, COSV59959310, COSV59961665; called by muse, mutect2, varscan2
- TTC9 | c.558C>A p.Y186* | Nonsense Mutation (SNP) | VAF 25/37 reads (68%) | catalogued as COSV56448182; called by muse, mutect2, varscan2
- TTYH1 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.782); catalogued as rs1363615135; called by muse, varscan2
- UNC13C | c.5171C>A p.S1724Y | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); catalogued as rs1415421209, COSV52871562; called by muse, mutect2, varscan2
- UNC5A | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs749730825, COSV52839070; called by muse, mutect2, varscan2
- VARS1 | c.1303G>A p.G435S | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65155180; called by muse, mutect2, varscan2
- VPS13A | c.1883G>A p.R628H | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62429527; called by muse, mutect2, varscan2
- VPS13B | c.3721C>T p.Q1241* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV62141367; called by muse, mutect2, varscan2
- XKR6 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 7/10 reads (70%) | catalogued as COSV58656108; called by muse, mutect2, varscan2
- ZDBF2 | c.4241C>T p.S1414F | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65625771; called by muse, mutect2, varscan2
- ZNF530 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as rs780728808, COSV60531517; called by muse, mutect2, varscan2
- ZNF607 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV67696823; called by muse, mutect2, varscan2
- ZNF676 | c.1826G>T p.S609I (on ENST00000650058; = p.S577I on NM_001001411.3) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.373); catalogued as COSV68093035; called by muse, mutect2, varscan2
- AFDN | c.387_389del p.K129del | In Frame Del (DEL) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- AJM1 | c.2804C>T p.T935M | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CC2D1B | c.1549del p.L517Cfs*53 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- DMD | c.3016A>G p.M1006V | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYSF | c.4322A>G p.Q1441R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.09); called by muse, mutect2
- GRIA3 | c.25C>A p.Q9K | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IPMK | c.920_921del p.E307Vfs*31 | Frame Shift Del (DEL) | VAF 14/29 reads (48%) | called by pindel, varscan2
- KIAA0232 | c.2353dup p.T785Nfs*3 | Frame Shift Ins (INS) | VAF 9/58 reads (16%) | called by mutect2, varscan2
- MED12L | c.744del p.K248Nfs*5 | Frame Shift Del (DEL) | VAF 68/185 reads (37%) | called by mutect2, pindel, varscan2
- PLXNB1 | c.2624C>A p.S875* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- POLH | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A33 | c.847G>C p.G283R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SRPX | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TENM1 | c.7708A>T p.R2570W | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2
- ZNF804B | c.2807A>T p.K936I | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- ALS2 | c.396G>A p.P132= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs374978798; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- AMOTL1 | c.432C>T p.L144= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as rs1328174556, COSV100133792; called by muse, mutect2, varscan2
- CCDC141 | c.3807T>C p.P1269= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV55373275; called by muse, mutect2, varscan2
- CD40 | c.273C>A p.V91= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV64847780; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1005C>T p.T335= (on ENST00000357886 / NM_001365728.1; = p.T321= on NM_016082.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 71/141 reads (50%) | catalogued as COSV59426826; called by muse, mutect2, varscan2
- CGN | c.1668G>T p.G556= | Silent (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- COL6A3 | c.8637G>A p.T2879= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs1417532835, COSV55088973; called by muse, mutect2, varscan2
- CPAMD8 | c.5496C>T p.D1832= (on ENST00000651564; = p.D1785= on NM_015692.5) | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99935255; called by muse, mutect2, varscan2
- CYP1A2 | c.1305C>T p.A435= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs745999166, COSV59659682; called by muse, mutect2, varscan2
- DCTPP1 | c.468G>T p.G156= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV100073538; called by muse, mutect2, varscan2
- ESRP2 | c.1350C>T p.S450= (on ENST00000565858 / NM_001365264.1; = p.S440= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs372468822; called by muse, mutect2, varscan2
- FKBP9 | c.1524C>T p.V508= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV54230741; called by mutect2, varscan2
- GABRD | c.135C>T p.D45= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs754323369, COSV66080540; ClinVar: likely benign; called by muse, mutect2
- GJB5 | c.723C>T p.D241= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs536768375, COSV58356165; called by muse, mutect2, varscan2
- GPR139 | c.81C>T p.F27= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV58501474; called by muse, varscan2
- GPR179 | c.1014C>T p.F338= (on ENST00000621958; = p.F337= on NM_001004334.4) | Silent (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- GRIA4 | c.2370C>T p.Y790= | Silent (SNP) | VAF 36/59 reads (61%) | catalogued as rs762639803, COSV56895709; called by muse, mutect2, varscan2
- HCN3 | c.2277G>T p.V759= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- IGHG1 | c.204G>A p.V68= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- LAMP3 | c.738G>A p.L246= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV55614833, COSV55615604; called by muse, mutect2, varscan2
- LSG1 | c.282C>T p.F94= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs755607314, COSV54570113; called by muse, mutect2, varscan2
- MED13L | c.1872G>A p.S624= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs1304593032, COSV99927738; called by muse, varscan2
- NDUFS6 | c.267C>T p.G89= | Silent (SNP) | VAF 31/47 reads (66%) | catalogued as rs769132703, COSV56876656; called by muse, mutect2, varscan2
- NEXMIF | c.1122G>T p.G374= | Silent (SNP) | VAF 22/22 reads (100%) | catalogued as COSV50030530; called by muse, mutect2, varscan2
- OBSCN | c.7251G>A p.T2417= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs371761770, COSV52778616; called by muse, mutect2, varscan2
- OR52E6 | c.480A>T p.P160= | Silent (SNP) | VAF 26/33 reads (79%) | catalogued as COSV61432058; called by muse, mutect2, varscan2
- OR6C74 | c.372C>A p.I124= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV59606424; called by muse, mutect2, varscan2
- PARP14 | c.1752C>T p.A584= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs951694337, COSV71734663; called by muse, mutect2, varscan2
- PCDHA5 | c.1278G>A p.A426= | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as COSV65352344; called by muse, mutect2, varscan2
- PLEKHA5 | c.1203C>T p.A401= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs150691984; called by muse, mutect2, varscan2
- PSMB10 | c.366G>A p.L122= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs772788981, COSV50452772; called by muse, mutect2, varscan2
- RASGRF2 | c.2037G>T p.L679= | Silent (SNP) | VAF 37/46 reads (80%) | catalogued as COSV99429267; called by muse, varscan2
- REG1B | c.399T>C p.N133= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV59305537; called by muse, mutect2, varscan2
- RYR1 | c.4089G>A p.A1363= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs761793739, COSV62107582; called by muse, mutect2, varscan2
- SEC16B | c.3138G>A p.R1046= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- SELENOO | c.1047C>T p.Y349= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as rs529648565, COSV101096802; called by muse, mutect2, varscan2
- STAB1 | c.5187C>T p.T1729= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs771251910, COSV58735998; called by muse, mutect2, varscan2
- TFAP2D | c.321C>T p.H107= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV50415159; called by muse, mutect2
- THSD4 | c.2574C>T p.A858= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs200392122; called by mutect2, varscan2
- TPR | c.336A>G p.Q112= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs368470841; called by muse, mutect2, varscan2
- TTN | c.4611C>A p.G1537= (on ENST00000591111; = p.G1491= on NM_003319.4) | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV59870835; called by muse, mutect2, varscan2
- XDH | c.2139G>T p.L713= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV65148593; called by muse, varscan2
- ZNF493 | c.1548C>T p.L516= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as rs760617541, COSV62750013; called by muse, mutect2, varscan2
- GATA3 | chr10:8051081 A>G | 5'Flank (SNP) | VAF 6/12 reads (50%) | catalogued as rs757480024; called by muse, mutect2, varscan2
- GCNT2 | c.926-34760G>A | Intron (SNP) | VAF 36/109 reads (33%) | catalogued as rs776266980, COSV53942266, COSV99399141; called by muse, mutect2, varscan2
- NRG1 | c.502+31347C>T | Intron (SNP) | VAF 4/36 reads (11%) | catalogued as rs916501513, COSV55163981; called by muse, varscan2
- TTN | c.10361-4501G>T | Intron (SNP) | VAF 17/39 reads (44%) | catalogued as COSV60048958; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23336C>T | Intron (SNP) | VAF 21/28 reads (75%) | catalogued as rs368889261; called by muse, mutect2, varscan2
